Somatic mutation profile of tumor specimen 0DGDWC from CCDI case PBBSCL, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Vital status: Dead; Primary diagnosis: Rhabdomyosarcoma, NOS; Tissue or organ of origin: Anterior mediastinum; Age at diagnosis: 18.3 years (6,690 days).
Specimen 0DGDWC: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) cdcba1dc-76f0-47ea-9b46-0019a3ba94b2.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DGDW4 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f1fa8574-32cc-414e-8f8b-8d517977bcd8

The open-access MAF lists 28 somatic variants for this specimen: 14 protein-altering or splice-affecting, 10 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 10, Silent 10, Frame Shift Del 2, 3'UTR 2, Intron 2, Splice Region 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- MYOD1 | c.365T>G p.L122R | Missense Mutation (SNP) | VAF 88/193 reads (46%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51452486; called by muse, mutect2, varscan2
- C11orf86 | c.16C>T p.R6* | Nonsense Mutation (SNP) | VAF 155/369 reads (42%) | catalogued as rs184409586, COSV58296975; called by muse, mutect2, varscan2
- CREBBP | c.6542A>G p.N2181S | Missense Mutation (SNP) | VAF 38/113 reads (34%) | SIFT tolerated, low confidence (0.41); PolyPhen benign (0); catalogued as rs768978068, COSV99062796; called by muse, mutect2, varscan2
- DELE1 | c.570A>G p.E190= | Splice Region (SNP) | VAF 112/352 reads (32%) | catalogued as rs571217703; called by muse, mutect2, varscan2
- EPB41L3 | c.2566G>A p.V856M | Missense Mutation (SNP) | VAF 84/229 reads (37%) | SIFT tolerated (0.07); PolyPhen benign (0.085); catalogued as rs779756258; called by muse, mutect2, varscan2
- MARCHF4 | c.1109del p.G370Afs*16 | Frame Shift Del (DEL) | VAF 40/80 reads (50%) | catalogued as COSV56103095; called by mutect2, varscan2
- SI | c.5057G>T p.R1686L | Missense Mutation (SNP) | VAF 130/425 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV52283536; called by muse, mutect2, varscan2
- TP53 | c.257del p.A86Dfs*37 | Frame Shift Del (DEL) | VAF 72/99 reads (73%) | catalogued as COSV53771066; called by mutect2, varscan2
- VWDE | c.2254C>T p.R752W | Missense Mutation (SNP) | VAF 76/487 reads (16%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.971); catalogued as rs375633029; called by muse, mutect2, varscan2
- CAV2 | c.418A>G p.I140V | Missense Mutation (SNP) | VAF 147/436 reads (34%) | SIFT tolerated (0.78); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- CSMD3 | c.1600G>T p.A534S (on ENST00000297405 / NM_001363185.1; = p.A430S on NM_052900.3) | Missense Mutation (SNP) | VAF 207/606 reads (34%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PTPRZ1 | c.5980C>A p.L1994I | Missense Mutation (SNP) | VAF 28/477 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.931); called by muse, mutect2
- TMEM200A | c.292T>C p.S98P | Missense Mutation (SNP) | VAF 112/411 reads (27%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.697); called by muse, mutect2, varscan2
- ZNF687 | c.1898T>G p.L633W | Missense Mutation (SNP) | VAF 47/165 reads (28%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.922); called by muse, mutect2, varscan2
- AC013477.1 | c.2136C>T p.R712= | Silent (SNP) | VAF 97/334 reads (29%) | called by muse, mutect2, varscan2
- DCC | c.1425A>G p.R475= | Silent (SNP) | VAF 115/194 reads (59%) | catalogued as COSV59143326; called by muse, mutect2, varscan2
- FAM135B | c.1878G>A p.G626= | Silent (SNP) | VAF 58/135 reads (43%) | catalogued as rs559587758, COSV99425103; called by muse, mutect2, varscan2
- FXYD5 | c.369C>A p.T123= | Silent (SNP) | VAF 112/280 reads (40%) | called by muse, mutect2, varscan2
- KMT2A | c.10698A>G p.E3566= | Silent (SNP) | VAF 186/541 reads (34%) | catalogued as rs782728957; called by muse, mutect2, varscan2
- MAN2C1 | c.2313C>A p.A771= | Silent (SNP) | VAF 8/96 reads (8%) | called by muse, mutect2
- MED13 | c.1998A>G p.K666= | Silent (SNP) | VAF 33/790 reads (4%) | called by muse, mutect2
- OR10A2 | c.60C>G p.T20= | Silent (SNP) | VAF 29/468 reads (6%) | called by muse, mutect2
- PNMA5 | c.135C>T p.P45= | Silent (SNP) | VAF 38/50 reads (76%) | catalogued as rs148357143; called by muse, mutect2, varscan2
- TSPOAP1 | c.4764C>T p.D1588= | Silent (SNP) | VAF 79/384 reads (21%) | catalogued as rs769090851, COSV52114848; called by muse, mutect2, varscan2
- C10orf105 | c.*3290G>C | 3'UTR (SNP) | VAF 85/210 reads (40%) | called by muse, mutect2, varscan2
- CNR1 | c.*44del | 3'UTR (DEL) | VAF 26/32 reads (81%) | catalogued as rs745517223; called by mutect2, varscan2
- DBNDD1 | c.320-63_320-62insT | Intron (INS) | VAF 10/21 reads (48%) | called by mutect2, varscan2
- NEK9 | c.1182+57C>A | Intron (SNP) | VAF 4/35 reads (11%) | called by mutect2, varscan2
